Somatic mutation profile of tumor specimen TCGA-A7-A26E-01B (aliquot TCGA-A7-A26E-01B-06D-A272-09) from TCGA case TCGA-A7-A26E, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Lobular carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 71.9 years (26,274 days).
Specimen TCGA-A7-A26E-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3a8f5c52-a1e4-4102-98cc-8996ea633744.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A7-A26E-10A (Blood Derived Normal), aliquot TCGA-A7-A26E-10A-01D-A167-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/45427c59-c2a1-44c8-a21d-128aa27c743e

The open-access MAF lists 39 somatic variants for this specimen: 28 protein-altering or splice-affecting, 11 silent.
By variant classification: Missense Mutation 23, Silent 11, Frame Shift Del 2, Frame Shift Ins 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NFE2L2 | c.242G>A p.G81D | Missense Mutation (SNP) | VAF 65/223 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67960014, COSV67960167, COSV67960618; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 27/117 reads (23%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABCA8 | c.4340G>A p.R1447Q | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as rs1344465458, COSV52206791; called by muse, mutect2, varscan2
- ALS2 | c.1234G>A p.E412K | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.718); catalogued as COSV51889626; called by muse, mutect2, varscan2
- BPIFB1 | c.401C>T p.T134M | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.286); catalogued as rs376198152; called by muse, mutect2, varscan2
- BRAP | c.100G>A p.E34K | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT tolerated (0.3); PolyPhen benign (0.025); catalogued as COSV58159682; called by muse, mutect2, varscan2
- CSPG4 | c.6957G>C p.Q2319H | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57898487; called by muse, mutect2, varscan2
- CWC27 | c.1060G>A p.D354N | Missense Mutation (SNP) | VAF 21/39 reads (54%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV66887223; called by muse, mutect2, varscan2
- E2F8 | c.595G>A p.E199K | Missense Mutation (SNP) | VAF 35/68 reads (51%) | SIFT deleterious (0.03); PolyPhen benign (0.012); catalogued as COSV100001496, COSV51464834; called by muse, mutect2, varscan2
- FHOD3 | c.4190G>A p.R1397Q (on ENST00000359247 / NM_001281739.3; = p.R1414Q on NM_025135.5) | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs201185019, COSV57180288; called by muse, mutect2, varscan2
- FSD2 | c.1411C>T p.P471S | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs200109394, COSV58009186; called by muse, mutect2, varscan2
- HK2 | c.2615C>T p.A872V | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.652); catalogued as rs1354116989, COSV51877163; called by muse, mutect2, varscan2
- KNL1 | c.952C>T p.Q318* (on ENST00000346991 / NM_170589.5; = p.Q292* on NM_144508.5) | Nonsense Mutation (SNP) | VAF 9/26 reads (35%) | catalogued as COSV61157494; called by muse, mutect2, varscan2
- MYO15A | c.8383G>A p.V2795M | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs144830391, COSV52760749; called by muse, mutect2, varscan2
- PRKAG3 | c.793G>A p.E265K | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52102859; called by muse, mutect2, varscan2
- QSOX2 | c.1660G>A p.V554M | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs780960010, COSV62394339; called by muse, mutect2, varscan2
- SDK2 | c.4948G>T p.D1650Y | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.389); catalogued as COSV66191187; called by muse, varscan2
- SFI1 | c.2221G>T p.A741S (on ENST00000400288 / NM_001007467.3; = p.A710S on NM_014775.4) | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV66291827; called by muse, mutect2, varscan2
- SLC4A2 | c.3697G>A p.E1233K | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as rs1251204971, COSV52541099; called by muse, mutect2, varscan2
- TEAD1 | c.487del p.T163Qfs*111 | Frame Shift Del (DEL) | VAF 14/38 reads (37%) | catalogued as COSV100531865; called by mutect2, pindel, varscan2
- TOGARAM1 | c.3970G>A p.D1324N | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV63893505; called by muse, mutect2, varscan2
- TPH2 | c.320A>G p.E107G | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as COSV61592975; called by muse, mutect2, varscan2
- UMODL1 | c.89C>T p.S30F | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV68576229; called by muse, mutect2, varscan2
- USP32 | c.590T>C p.I197T | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.158); catalogued as rs138623701; called by mutect2, varscan2
- DDX52 | c.1631G>C p.G544A | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT tolerated (0.62); PolyPhen benign (0.003); called by muse, varscan2
- KDM5C | c.3226_3227insCGACAGG p.L1076Pfs*56 | Frame Shift Ins (INS) | VAF 9/40 reads (23%) | called by mutect2, varscan2*
- RUNX1 | c.286dup p.D96Gfs*15 (on ENST00000344691 / NM_001001890.3; = p.D123Gfs*15 on NM_001754.5) | Frame Shift Ins (INS) | VAF 9/32 reads (28%) | called by mutect2, pindel, varscan2
- TCF12 | c.143del p.G48Dfs*39 | Frame Shift Del (DEL) | VAF 6/35 reads (17%) | called by mutect2, pindel, varscan2
- ABCA13 | c.12825C>T p.G4275= | Silent (SNP) | VAF 7/71 reads (10%) | catalogued as rs762367233, COSV68944007, COSV68951470; called by mutect2, varscan2
- ARHGAP28 | c.1701C>A p.R567= (on ENST00000383472 / NM_001366230.1; = p.R408= on NM_001010000.3) | Silent (SNP) | VAF 13/45 reads (29%) | catalogued as COSV51641925, COSV99151432; called by muse, mutect2, varscan2
- B3GLCT | c.1221C>T p.L407= | Silent (SNP) | VAF 28/75 reads (37%) | catalogued as rs139927237; called by muse, mutect2, varscan2
- CACFD1 | c.477G>T p.A159= | Silent (SNP) | VAF 5/54 reads (9%) | catalogued as rs781807306; called by muse, mutect2
- CEP55 | c.1128A>G p.Q376= | Silent (SNP) | VAF 7/36 reads (19%) | catalogued as COSV65185450; called by muse, mutect2, varscan2
- FLG | c.4704C>T p.A1568= | Silent (SNP) | VAF 103/216 reads (48%) | catalogued as rs766533034, COSV100910376, COSV64238428; called by muse, mutect2, varscan2
- HECTD2 | c.1641C>T p.I547= | Silent (SNP) | VAF 21/128 reads (16%) | catalogued as COSV53222804; called by muse, mutect2, varscan2
- KIF26B | c.561C>T p.C187= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as rs181190211; called by mutect2, varscan2
- LRP1B | c.7899C>T p.F2633= | Silent (SNP) | VAF 22/77 reads (29%) | catalogued as COSV67246917, COSV67248322; called by muse, mutect2, varscan2
- PCGF1 | c.180C>T p.I60= | Silent (SNP) | VAF 13/52 reads (25%) | catalogued as COSV52043653; called by muse, mutect2, varscan2
- RETREG2 | c.780G>A p.K260= | Silent (SNP) | VAF 26/89 reads (29%) | catalogued as COSV56088178; called by muse, mutect2, varscan2
